Somatic mutation profile of tumor specimen TCGA-BJ-A0Z0-01A (aliquot TCGA-BJ-A0Z0-01A-11D-A10S-08) from TCGA case TCGA-BJ-A0Z0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 55.7 years (20,361 days).
Specimen TCGA-BJ-A0Z0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd9b45b9-658e-475a-b8b3-ed0bd6472179.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0Z0-10A (Blood Derived Normal), aliquot TCGA-BJ-A0Z0-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88700e06-65ef-4dff-8d04-6e4f83475994

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 4, Frame Shift Del 2, Splice Site 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.548del p.K183Rfs*16 | Frame Shift Del (DEL) | VAF 81/176 reads (46%) | catalogued as rs1554900593, COSV64301859; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAM15 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV55128098; called by muse, mutect2, varscan2
- AGBL1 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.249); catalogued as COSV69803984; called by mutect2, varscan2
- BDP1 | c.2714T>C p.M905T | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1037252818, COSV62432454; called by muse, mutect2, varscan2
- CFAP46 | c.6862G>A p.A2288T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV54154715; called by muse, mutect2, varscan2
- ELOA2 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV55293008; called by muse, mutect2
- ENPP2 | c.2309G>A p.S770N (on ENST00000075322 / NM_001040092.3; = p.S822N on NM_006209.5) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV50021194; called by muse, mutect2, varscan2
- GEMIN5 | c.2962A>T p.I988F | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs760029026, COSV53562087; called by muse, mutect2, varscan2
- HEYL | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs139668981; called by muse, mutect2, varscan2
- MUC7 | c.50T>C p.F17S | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV59219221; called by muse, mutect2, varscan2
- N4BP2 | c.1541A>G p.D514G | Missense Mutation (SNP) | VAF 142/292 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764361125, COSV54704090; called by muse, varscan2
- NCAPH2 | c.1479G>T p.Q493H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52688508; called by muse, mutect2
- PCDHB1 | c.2436G>T p.Q812H | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); catalogued as COSV60631818; called by muse, mutect2, varscan2
- PRKDC | c.7796G>A p.S2599N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.905); catalogued as rs868395298, COSV58057032; called by muse, mutect2
- PTEN | c.416T>A p.L139* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as CD075527, CM033667, CM983502, COSV64297098, COSV64299522; called by muse, mutect2, varscan2
- RAP1GAP | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV51574453; called by muse, mutect2
- RO60 | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV66474203; called by muse, mutect2, varscan2
- SEC24B | c.3588+2T>A p.X1196_splice | Splice Site (SNP) | VAF 28/222 reads (13%) | catalogued as COSV54502237; called by muse, mutect2, varscan2
- SHROOM3 | c.1009G>C p.A337P | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV56033280; called by muse, mutect2, varscan2
- SHROOM3 | c.2426A>T p.Y809F | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV56033289; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1066G>C p.A356P | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV61457032; called by muse, mutect2, varscan2
- ZNF565 | c.860G>C p.G287A (on ENST00000355114; = p.G247A on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs901859194, COSV58411195; called by muse, mutect2
- ANKS1A | c.1974_1996del p.E659Gfs*4 | Frame Shift Del (DEL) | VAF 74/320 reads (23%) | called by mutect2, pindel
- IGHV3OR16-8 | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); called by mutect2, varscan2
- FCGBP | c.10530A>G p.A3510= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs764014899; called by muse, mutect2, varscan2
- MALSU1 | c.597T>C p.Y199= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as rs894494811, COSV51688088; called by muse, mutect2
- SNTB2 | c.642G>A p.P214= | Silent (SNP) | VAF 122/410 reads (30%) | catalogued as rs143099113; called by muse, mutect2, varscan2
- TG | c.666T>C p.S222= | Silent (SNP) | VAF 49/145 reads (34%) | catalogued as COSV55083422; called by muse, mutect2, varscan2
- FAM169B | n.788G>A | RNA (SNP) | VAF 15/73 reads (21%) | catalogued as rs750487100, COSV60569352; called by muse, mutect2, varscan2
